Somatic mutation profile of tumor specimen ALCH-B46T-TTP1-A (aliquot ALCH-B46T-TTP1-A-1-0-D-A80E-36) from ALCHEMIST case ALCH-B46T, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 65.6 years (23,943 days).
Specimen ALCH-B46T-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d1923db5-3419-4bd0-aafc-181c62e80f57.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B46T-NB1-A (Blood Derived Normal), aliquot ALCH-B46T-NB1-A-1-0-D-A80E-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5b953636-440e-41ae-9f9f-1e1f775dff58

The open-access MAF lists 165 somatic variants for this specimen: 131 protein-altering or splice-affecting, 25 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 111, Silent 25, Nonsense Mutation 7, Splice Region 5, Frame Shift Del 4, Intron 4, RNA 3, Splice Site 2, In Frame Del 1, Frame Shift Ins 1, 3'Flank 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 28/249 reads (11%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- KRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 28/249 reads (11%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- LPIN2 | c.1550G>A p.R517H | Missense Mutation (SNP) | VAF 14/121 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs756933588; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ADCY8 | c.3190G>T p.A1064S | Missense Mutation (SNP) | VAF 12/132 reads (9%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.953); catalogued as rs1430037556; called by muse, mutect2
- AMH | c.181G>A p.G61R | Missense Mutation (SNP) | VAF 19/147 reads (13%) | SIFT tolerated (0.89); PolyPhen benign (0.02); catalogued as rs769745728; called by muse, mutect2, varscan2
- ARHGEF3 | c.293G>C p.R98P | Missense Mutation (SNP) | VAF 29/198 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV56329534, COSV99574898; called by muse, mutect2, varscan2
- BAAT | c.1156G>A p.G386R | Missense Mutation (SNP) | VAF 52/351 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM133631; called by muse, mutect2, varscan2
- BBS12 | c.778C>T p.H260Y | Missense Mutation (SNP) | VAF 17/126 reads (13%) | SIFT tolerated (0.29); PolyPhen benign (0.015); catalogued as rs1410719442; called by muse, mutect2, varscan2
- CDKN1B | c.343del p.A115Rfs*4 | Frame Shift Del (DEL) | VAF 5/56 reads (9%) | catalogued as COSV57431791; called by mutect2, pindel, varscan2
- CLEC16A | c.367G>A p.V123I | Missense Mutation (SNP) | VAF 17/149 reads (11%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.995); catalogued as rs776955669, COSV68499412; called by muse, mutect2
- CNKSR2 | c.800A>T p.H267L | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.179); catalogued as COSV54269043; called by muse, mutect2, varscan2
- CSMD3 | c.5266C>A p.P1756T (on ENST00000297405 / NM_001363185.1; = p.P1652T on NM_052900.3) | Missense Mutation (SNP) | VAF 15/191 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as rs1424943206, COSV52269302; called by muse, mutect2
- CTNNA2 | c.1150G>T p.V384L | Missense Mutation (SNP) | VAF 17/85 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.882); catalogued as COSV58187529; called by muse, mutect2, varscan2
- DNAH7 | c.5279G>T p.R1760I | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.035); catalogued as COSV56753010; called by muse, mutect2, varscan2
- DPP10 | c.214del p.E72Kfs*35 | Frame Shift Del (DEL) | VAF 16/161 reads (10%) | catalogued as COSV100067295; called by mutect2, pindel, varscan2
- EBF3 | c.1499G>T p.S500I (on ENST00000355311 / NM_001375392.1; = p.S491I on NM_001005463.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/112 reads (11%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.035); catalogued as COSV62471376, COSV62475439; called by muse, varscan2
- FANK1 | c.398G>T p.G133V | Missense Mutation (SNP) | VAF 32/185 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV64156607; called by muse, mutect2, varscan2
- GGH | c.472G>T p.V158L | Missense Mutation (SNP) | VAF 12/103 reads (12%) | SIFT tolerated (0.42); PolyPhen benign (0.001); catalogued as COSV52649271; called by muse, mutect2, varscan2
- KLHL6 | c.1693G>T p.G565W | Missense Mutation (SNP) | VAF 25/195 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58064615; called by muse, mutect2, varscan2
- LRBA | c.3974C>T p.S1325L | Missense Mutation (SNP) | VAF 12/85 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.11); catalogued as COSV63953694; called by muse, mutect2, varscan2
- MAGT1 | c.11G>T p.R4L (on ENST00000618282 / NM_001367916.1; = p.R36L on NM_032121.5) | Missense Mutation (SNP) | VAF 26/279 reads (9%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0.003); catalogued as rs782595858; called by muse, mutect2
- MAP1A | c.7099C>A p.P2367T | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.022); catalogued as rs1385042345; called by muse, mutect2, varscan2
- MUC16 | c.33149G>T p.S11050I | Missense Mutation (SNP) | VAF 9/74 reads (12%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.013); catalogued as COSV67506735; called by muse, mutect2, varscan2
- NCALD | c.424G>A p.E142K | Missense Mutation (SNP) | VAF 28/454 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.109); catalogued as COSV55272086; called by muse, mutect2
- OR10A4 | c.850C>G p.P284A | Missense Mutation (SNP) | VAF 16/225 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV65842566; called by muse, mutect2
- P2RY10 | c.907A>G p.I303V | Missense Mutation (SNP) | VAF 21/224 reads (9%) | SIFT tolerated (0.65); PolyPhen benign (0.173); catalogued as rs769100470; called by muse, mutect2, varscan2
- PCDHB11 | c.2002C>T p.Q668* | Nonsense Mutation (SNP) | VAF 22/162 reads (14%) | catalogued as rs146687868; called by muse, mutect2, varscan2
- PCDHB4 | c.1586G>T p.R529L | Missense Mutation (SNP) | VAF 58/388 reads (15%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.025); catalogued as rs1430660471, COSV99522076; called by muse, varscan2
- PLA2G4C | c.1348C>T p.P450S | Missense Mutation (SNP) | VAF 16/85 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs768032279, COSV62785687; called by muse, mutect2, varscan2
- PLEKHH3 | c.391C>T p.Q131* | Nonsense Mutation (SNP) | VAF 10/191 reads (5%) | catalogued as rs1410868320; called by muse, mutect2
- POU3F4 | c.290G>T p.R97L | Missense Mutation (SNP) | VAF 21/165 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.011); catalogued as COSV64538791, COSV64540956; called by muse, mutect2, varscan2
- PTPRB | c.5477G>T p.G1826V | Missense Mutation (SNP) | VAF 11/103 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99718060; called by muse, mutect2, varscan2
- SLC44A5 | c.427G>T p.E143* | Nonsense Mutation (SNP) | VAF 15/83 reads (18%) | catalogued as COSV63758152; called by muse, mutect2, varscan2
- SOX11 | c.399C>A p.S133R | Missense Mutation (SNP) | VAF 30/169 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.067); catalogued as rs562403473, COSV58985267; called by muse, varscan2
- TENM1 | c.4416C>A p.D1472E | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV64427420; called by muse, mutect2, varscan2
- UNC13B | c.382G>C p.E128Q | Missense Mutation (SNP) | VAF 24/124 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.949); catalogued as rs374929028; called by muse, varscan2
- USP53 | c.1969G>A p.E657K | Missense Mutation (SNP) | VAF 17/73 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.129); catalogued as rs773159522, COSV56793749; called by muse, mutect2, varscan2
- WNT3 | c.179G>A p.R60H | Missense Mutation (SNP) | VAF 35/195 reads (18%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.999); catalogued as rs758209963; called by muse, mutect2, varscan2
- ZBED6 | c.1375C>G p.Q459E | Missense Mutation (SNP) | VAF 23/394 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs1190539131; called by muse, mutect2
- ZNF226 | c.1075G>A p.A359T | Missense Mutation (SNP) | VAF 15/278 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.039); catalogued as rs1271358989; called by muse, mutect2
- ZP4 | c.846T>G p.H282Q | Missense Mutation (SNP) | VAF 24/92 reads (26%) | SIFT tolerated (0.42); PolyPhen benign (0.014); catalogued as COSV63911868; called by muse, mutect2, varscan2
- AC127029.3 | c.743A>T p.E248V | Missense Mutation (SNP) | VAF 20/224 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.979); called by muse, mutect2
- ADGRL2 | c.1093A>T p.I365F | Missense Mutation (SNP) | VAF 32/211 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- AFF2 | c.380A>T p.Q127L | Missense Mutation (SNP) | VAF 11/83 reads (13%) | SIFT tolerated (0.31); PolyPhen benign (0.31); called by muse, mutect2, varscan2
- ALDH1L1 | c.2338C>A p.P780T | Missense Mutation (SNP) | VAF 13/70 reads (19%) | SIFT tolerated (0.54); PolyPhen benign (0.07); called by muse, mutect2
- ANKRD52 | c.607G>T p.D203Y | Missense Mutation (SNP) | VAF 14/187 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- ANOS1 | c.808G>T p.G270* | Nonsense Mutation (SNP) | VAF 31/256 reads (12%) | called by muse, mutect2, varscan2
- ASXL2 | c.3416G>T p.R1139M | Missense Mutation (SNP) | VAF 25/151 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); called by muse, mutect2, varscan2
- ATP1B4 | c.307del p.A103Pfs*9 (on ENST00000218008 / NM_001142447.3; = p.A103Pfs*5 on NM_012069.5) | Frame Shift Del (DEL) | VAF 9/89 reads (10%) | called by mutect2, pindel, varscan2
- ATP2B3 | c.2527C>A p.R843S | Missense Mutation (SNP) | VAF 30/207 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- BCL9 | c.1823G>T p.G608V | Missense Mutation (SNP) | VAF 31/306 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.044); called by muse, mutect2
- BOD1 | c.212A>T p.D71V | Missense Mutation (SNP) | VAF 20/196 reads (10%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.993); called by muse, mutect2
- C2CD5 | c.2314del p.H772Mfs*2 | Frame Shift Del (DEL) | VAF 12/98 reads (12%) | called by mutect2, pindel, varscan2
- CBR4 | c.622G>A p.E208K | Missense Mutation (SNP) | VAF 10/185 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.492); called by muse, mutect2
- CCL5 | c.25G>C p.A9P | Missense Mutation (SNP) | VAF 25/198 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.308); called by muse, mutect2, varscan2
- CENPF | c.4279C>T p.Q1427* | Nonsense Mutation (SNP) | VAF 5/64 reads (8%) | called by muse, mutect2
- CERS4 | c.243C>A p.N81K | Missense Mutation (SNP) | VAF 26/261 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- CLTC | c.3570C>G p.I1190M | Missense Mutation (SNP) | VAF 14/170 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.679); called by muse, mutect2
- COL4A4 | c.1046G>T p.R349L | Missense Mutation (SNP) | VAF 43/362 reads (12%) | SIFT tolerated (0.82); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CYP8B1 | c.377C>G p.A126G | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.561); called by muse, mutect2
- DCAF12L1 | c.236C>G p.A79G | Missense Mutation (SNP) | VAF 19/89 reads (21%) | SIFT tolerated (0.24); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- DCAF8L1 | c.712C>T p.H238Y | Missense Mutation (SNP) | VAF 29/140 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DDX18 | c.606G>T p.M202I | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); called by muse, mutect2, varscan2
- DEPDC7 | c.115T>A p.W39R (on ENST00000241051 / NM_001077242.2; = p.W30R on NM_139160.2) | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); called by muse, varscan2
- EFCAB6 | c.3880-2A>G p.X1294_splice | Splice Site (SNP) | VAF 10/66 reads (15%) | called by muse, mutect2
- EXOC3L4 | c.2094G>T p.E698D | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT tolerated (0.46); PolyPhen benign (0.003); called by muse, mutect2
- FCRL4 | c.306A>T p.S102= | Splice Region (SNP) | VAF 7/65 reads (11%) | called by muse, mutect2, varscan2
- FLRT2 | c.175C>T p.L59F | Missense Mutation (SNP) | VAF 21/160 reads (13%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- GABRA4 | c.1567C>G p.R523G | Missense Mutation (SNP) | VAF 18/188 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- HIC2 | c.319C>T p.P107S | Missense Mutation (SNP) | VAF 22/134 reads (16%) | SIFT tolerated (0.75); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- IL6ST | c.2017A>C p.R673= | Splice Region (SNP) | VAF 28/141 reads (20%) | called by muse, mutect2, varscan2
- JAG2 | c.2810A>T p.Q937L | Missense Mutation (SNP) | VAF 18/140 reads (13%) | SIFT tolerated (0.14); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- KCNA5 | c.1133A>T p.E378V | Missense Mutation (SNP) | VAF 24/172 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.297); called by muse, mutect2, varscan2
- KIF9 | c.694T>A p.S232T | Missense Mutation (SNP) | VAF 11/200 reads (6%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.838); called by muse, mutect2
- KRT18 | c.267C>G p.D89E | Missense Mutation (SNP) | VAF 26/194 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.211); called by muse, mutect2, varscan2
- KRT9 | c.380A>G p.Y127C | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.02); called by muse, mutect2
- LRRC66 | c.1120G>T p.D374Y | Missense Mutation (SNP) | VAF 22/151 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- LRRFIP2 | c.983G>A p.S328N | Missense Mutation (SNP) | VAF 31/254 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MAGEE1 | c.97G>C p.A33P | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.953); called by muse, varscan2
- MEGF8 | c.7710G>T p.W2570C (on ENST00000251268 / NM_001271938.2; = p.W2503C on NM_001410.3) | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.811); called by muse, mutect2, varscan2
- MUC12 | c.15982G>T p.V5328L (on ENST00000379442; = p.V5185L on NM_001164462.1) | Missense Mutation (SNP) | VAF 26/214 reads (12%) | SIFT deleterious (0.01); called by muse, mutect2, varscan2
- MUC16 | c.37198C>A p.Q12400K | Missense Mutation (SNP) | VAF 26/132 reads (20%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.119); called by muse, mutect2, varscan2
- MUC16 | c.12352T>A p.W4118R | Missense Mutation (SNP) | VAF 17/131 reads (13%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- MYO15B | c.7984-3C>A | Splice Region (SNP) | VAF 9/67 reads (13%) | called by muse, varscan2
- MYOM1 | c.4645C>A p.Q1549K | Missense Mutation (SNP) | VAF 30/198 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.291); called by muse, mutect2, varscan2
- NDST1 | c.80G>T p.C27F | Missense Mutation (SNP) | VAF 16/97 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- NEK10 | c.321G>C p.Q107H | Missense Mutation (SNP) | VAF 15/119 reads (13%) | SIFT tolerated (0.16); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- NLRP2 | c.1856A>G p.K619R | Missense Mutation (SNP) | VAF 29/431 reads (7%) | SIFT tolerated (0.29); PolyPhen benign (0.42); called by muse, mutect2
- NRAP | c.1084C>A p.Q362K | Missense Mutation (SNP) | VAF 34/120 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.068); called by muse, mutect2, varscan2
- NRK | c.4698C>A p.Y1566* | Nonsense Mutation (SNP) | VAF 14/112 reads (13%) | called by muse, mutect2, varscan2
- NUP153 | c.4016dup p.G1340Rfs*30 | Frame Shift Ins (INS) | VAF 24/184 reads (13%) | called by mutect2, pindel, varscan2
- ONECUT2 | c.1207A>T p.M403L | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.749); called by muse, varscan2
- OR52R1 | c.551A>T p.H184L | Missense Mutation (SNP) | VAF 19/146 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OR5J2 | c.654C>A p.Y218* | Nonsense Mutation (SNP) | VAF 34/255 reads (13%) | called by muse, mutect2, varscan2
- OR6A2 | c.171C>A p.H57Q | Missense Mutation (SNP) | VAF 28/213 reads (13%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.802); called by muse, mutect2, varscan2
- OR9Q2 | c.882C>A p.N294K | Missense Mutation (SNP) | VAF 13/70 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.155); called by muse, mutect2, varscan2
- OTOGL | c.1907T>C p.I636T (on ENST00000547103; = p.I627T on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/127 reads (11%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.889); called by muse, mutect2, varscan2
- PAPPA | c.4441C>G p.P1481A | Missense Mutation (SNP) | VAF 7/150 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- PCLO | c.13119G>T p.M4373I | Missense Mutation (SNP) | VAF 13/100 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- PEAR1 | c.1158G>C p.W386C | Missense Mutation (SNP) | VAF 13/81 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PHF19 | c.1682G>C p.R561T | Missense Mutation (SNP) | VAF 9/81 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PHLDB2 | c.1571G>T p.S524I | Missense Mutation (SNP) | VAF 20/129 reads (16%) | SIFT tolerated (0.25); PolyPhen benign (0); called by muse, mutect2, varscan2
- PIM1 | c.37C>A p.R13S | Missense Mutation (SNP) | VAF 25/210 reads (12%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- PRDM6 | c.1175T>G p.M392R | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT tolerated (0.47); PolyPhen benign (0.139); called by muse, mutect2, varscan2
- PTPRB | c.5476G>T p.G1826W | Missense Mutation (SNP) | VAF 11/103 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RABL3 | c.194G>T p.W65L | Missense Mutation (SNP) | VAF 27/179 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- RELN | c.4643A>G p.E1548G | Missense Mutation (SNP) | VAF 12/131 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.977); called by muse, mutect2
- RELN | c.3831G>T p.M1277I | Missense Mutation (SNP) | VAF 40/262 reads (15%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.577); called by muse, mutect2, varscan2
- RIMS2 | c.1216A>T p.N406Y (on ENST00000666250 / NM_001348490.2; = p.N214Y on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 51/167 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.819); called by muse, mutect2, varscan2
- RNF8 | c.226A>G p.I76V | Missense Mutation (SNP) | VAF 27/152 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- RTL1 | c.2777C>T p.P926L | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.723); called by muse, mutect2, varscan2
- SCML2 | c.269G>T p.G90V | Missense Mutation (SNP) | VAF 31/308 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SCN3A | c.4627A>G p.M1543V | Missense Mutation (SNP) | VAF 19/158 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.406); called by muse, mutect2, varscan2
- SF3B1 | c.1169G>T p.R390I | Missense Mutation (SNP) | VAF 16/156 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- SOX2 | c.887A>T p.Q296L | Missense Mutation (SNP) | VAF 34/256 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.254); called by muse, mutect2, varscan2
- SPG11 | c.666C>T p.I222= | Splice Region (SNP) | VAF 38/262 reads (15%) | called by muse, mutect2, varscan2
- SPTA1 | c.5203C>G p.R1735G | Missense Mutation (SNP) | VAF 28/414 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.006); called by muse, mutect2
- STYXL2 | c.3265_3273del p.T1089_S1091del | In Frame Del (DEL) | VAF 68/359 reads (19%) | called by mutect2, pindel, varscan2
- THSD7A | c.1247G>T p.G416V | Missense Mutation (SNP) | VAF 18/98 reads (18%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.949); called by muse, mutect2
- TREX1 | c.722C>A p.T241N (on ENST00000625293 / NM_033629.6; = p.T231N on NM_007248.5) | Missense Mutation (SNP) | VAF 49/470 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- TRIM39 | c.1456A>G p.T486A | Missense Mutation (SNP) | VAF 51/287 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.718); called by muse, mutect2, varscan2
- TRIML2 | c.580C>A p.L194I | Missense Mutation (SNP) | VAF 16/204 reads (8%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.994); called by muse, mutect2
- TRPC7 | c.289C>A p.L97M | Missense Mutation (SNP) | VAF 25/163 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- UBXN6 | c.212G>C p.W71S | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT tolerated (0.32); PolyPhen benign (0); called by muse, mutect2, varscan2
- VSTM2A | c.211G>T p.D71Y | Missense Mutation (SNP) | VAF 16/75 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.119); called by muse, mutect2
- WDFY4 | c.8957C>A p.T2986K | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); called by muse, mutect2
- XIRP1 | c.2594C>T p.P865L | Missense Mutation (SNP) | VAF 12/105 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- ZNF185 | c.432G>T p.L144= | Splice Region (SNP) | VAF 12/88 reads (14%) | called by muse, varscan2
- ZNF624 | c.2242G>C p.G748R | Missense Mutation (SNP) | VAF 16/77 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZNF79 | c.232+1G>T p.X78_splice | Splice Site (SNP) | VAF 7/58 reads (12%) | called by muse, mutect2, varscan2
- ZSCAN2 | c.719A>T p.H240L | Missense Mutation (SNP) | VAF 41/305 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); called by muse, mutect2, varscan2
- ADAMTS12 | c.2946A>C p.T982= | Silent (SNP) | VAF 27/204 reads (13%) | called by muse, mutect2, varscan2
- ASXL3 | c.4350T>C p.S1450= | Silent (SNP) | VAF 10/72 reads (14%) | called by muse, mutect2, varscan2
- CDH10 | c.1347T>G p.R449= | Silent (SNP) | VAF 19/162 reads (12%) | called by muse, mutect2, varscan2
- CELSR3 | c.9628C>A p.R3210= | Silent (SNP) | VAF 16/116 reads (14%) | catalogued as COSV99373327; called by muse, mutect2, varscan2
- CYLC1 | c.387A>G p.K129= | Silent (SNP) | VAF 7/39 reads (18%) | catalogued as rs149146924; called by muse, mutect2, varscan2
- H2AC15 | c.309C>T p.I103= | Silent (SNP) | VAF 39/356 reads (11%) | catalogued as COSV57585540; called by muse, mutect2, varscan2
- IMPG2 | c.426G>A p.E142= | Silent (SNP) | VAF 28/249 reads (11%) | called by muse, mutect2, varscan2
- KLHL34 | c.489G>A p.A163= | Silent (SNP) | VAF 7/45 reads (16%) | called by muse, mutect2
- MAGEA12 | c.84G>C p.A28= | Silent (SNP) | VAF 18/148 reads (12%) | catalogued as rs1556833291; called by muse, mutect2, varscan2
- MAN1B1 | c.909G>A p.L303= | Silent (SNP) | VAF 17/122 reads (14%) | catalogued as COSV100858085; called by muse, mutect2, varscan2
- NCOR2 | c.6018G>C p.P2006= | Silent (SNP) | VAF 10/84 reads (12%) | catalogued as rs529821999; called by muse, mutect2, varscan2
- OTOG | c.8436G>A p.E2812= | Silent (SNP) | VAF 30/73 reads (41%) | called by muse, mutect2, varscan2
- PKD1 | c.5322C>T p.P1774= | Silent (SNP) | VAF 37/311 reads (12%) | catalogued as rs771718105; called by muse, mutect2, varscan2
- PRKCG | c.1881C>A p.I627= | Silent (SNP) | VAF 46/361 reads (13%) | called by muse, mutect2, varscan2
- PTCH1 | c.1593C>T p.I531= | Silent (SNP) | VAF 38/317 reads (12%) | catalogued as rs587780694; ClinVar: likely benign; called by muse, mutect2, varscan2
- RELN | c.7512C>A p.G2504= | Silent (SNP) | VAF 36/289 reads (12%) | called by muse, mutect2, varscan2
- REPS2 | c.1911C>G p.L637= | Silent (SNP) | VAF 9/86 reads (10%) | catalogued as rs1257904967; called by muse, mutect2, varscan2
- SUPT20HL1 | c.990C>A p.A330= | Silent (SNP) | VAF 16/121 reads (13%) | called by muse, mutect2, varscan2
- THEG | c.375G>T p.R125= | Silent (SNP) | VAF 15/131 reads (11%) | called by muse, mutect2
- TLN2 | c.1521C>T p.H507= | Silent (SNP) | VAF 27/227 reads (12%) | catalogued as rs754033042, COSV60892218; called by muse, mutect2, varscan2
- TPO | c.45C>T p.C15= | Silent (SNP) | VAF 26/332 reads (8%) | catalogued as rs201781569; called by muse, mutect2
- TRAV12-3 | c.90T>A p.P30= | Silent (SNP) | VAF 12/57 reads (21%) | catalogued as rs201128400; called by muse, mutect2, varscan2
- TRPC7 | c.102C>T p.N34= | Silent (SNP) | VAF 23/110 reads (21%) | catalogued as rs368448135; called by muse, mutect2, varscan2
- WFS1 | c.1788G>A p.K596= | Silent (SNP) | VAF 13/146 reads (9%) | catalogued as COSV56988455; called by muse, mutect2, varscan2
- ZNF98 | c.1506C>A p.S502= | Silent (SNP) | VAF 22/154 reads (14%) | catalogued as rs1454286220, COSV100757439; called by muse, mutect2, varscan2
- ADAMTS18 | c.91-16A>T | Intron (SNP) | VAF 7/63 reads (11%) | called by muse, mutect2, varscan2
- CICP28 | chr7:56811907 C>A | 3'Flank (SNP) | VAF 22/157 reads (14%) | catalogued as rs782512930; called by muse, mutect2, varscan2
- CLNK | c.630+514G>T | Intron (SNP) | VAF 16/131 reads (12%) | called by muse, mutect2, varscan2
- IQCN | c.2617-201A>T | Intron (SNP) | VAF 8/65 reads (12%) | catalogued as rs958003784; called by muse, mutect2, varscan2
- NPC2 | c.-11C>T | 5'UTR (SNP) | VAF 11/342 reads (3%) | catalogued as COSV99467176; called by muse, mutect2
- SCAND2P | n.612G>A | RNA (SNP) | VAF 31/253 reads (12%) | called by muse, mutect2, varscan2
- SSPOP | n.1515G>T | RNA (SNP) | VAF 34/293 reads (12%) | called by muse, mutect2, varscan2
- SSPOP | n.11436T>A | RNA (SNP) | VAF 14/91 reads (15%) | called by muse, mutect2, varscan2
- ZNF44 | c.147+1998C>T | Intron (SNP) | VAF 22/190 reads (12%) | called by muse, mutect2, varscan2
